Gene-level copy-number profile of tumor specimen TCGA-EB-A6QZ-01A from TCGA case TCGA-EB-A6QZ, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 76.9 years (28,078 days).
Specimen TCGA-EB-A6QZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.30eac8f9-4b10-4d85-a1b9-8fb9c9a2b4c0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EB-A6QZ-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c5ba0d6f-e04a-43dc-a4cb-aabacc210b3f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 14,020; copy number 2: 45,786.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EB-A6QZ-01A-12D-A32M-01): tumor purity 0.9, ploidy 1.76, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,064,089–181,591,969, 5 genes: LINC00290, AC019235.1, LINC02500, AC093840.1, AC093840.2.
- chr10:87,751,512–88,049,823, 9 genes: ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 11,599. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
